Gene-level copy-number profile of tumor specimen TCGA-A7-A6VX-01A from TCGA case TCGA-A7-A6VX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.6 years (25,066 days).
Specimen TCGA-A7-A6VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5856d23e-c230-4122-abf1-fa304bdceee9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A6VX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1d448c8-58c6-450a-8334-c2fb51b5c9b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,617; copy number 2: 22,908; copy number 3: 15,553; copy number 4: 7,969; copy number 5: 5,422; copy number 6: 1,599; copy number 7: 1,708; copy number 8: 1,372; copy number 9: 412; copy number 10: 245.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A6VX-01A-12D-A33D-01): tumor purity 0.8, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,711,226, 14 genes (within-gene range 0–1): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,586 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,288,460–248,919,946, 2,119 genes, copy number 5–10 (broad region; genes not listed).
- chr3:133,490,824–198,222,513, 1,124 genes, copy number 8–9 (broad region; genes not listed).
- chr4:54,836,041–57,353,329, 68 genes, copy number 6–7 (broad region; genes not listed).
- chr6:133,502,252–133,892,802, 1 gene, copy number 5 (within-gene range 4–5): TARID.
- chr6:133,540,784–170,738,536, 630 genes, copy number 5 (broad region; genes not listed).
- chr7:79,335,780–96,322,147, 200 genes, copy number 6 (broad region; genes not listed).
- chr8:2,873,525–4,994,972, 7 genes, copy number 5 (within-gene range 2–5): AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1.
- chr8:6,044,353–7,187,316, 36 genes, copy number 5 (within-gene range 2–5): AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3, DEFA11P, DEFA7P, DEFA5, AF238378.1, AF228730.5, AF228730.2, RPS3AP30, SNRPCP6.
- chr8:13,536,029–13,536,135, 1 gene, copy number 5: RNA5SP255.
- chr8:28,767,661–30,814,314, 55 genes, copy number 5 (within-gene range 2–5): INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB.
- chr8:38,030,534–54,247,906, 269 genes, copy number 5 (broad region; genes not listed).
- chr8:55,696,424–63,234,911, 118 genes, copy number 5–8 (broad region; genes not listed).
- chr8:64,331,927–145,066,685, 1,267 genes, copy number 5–8 (broad region; genes not listed).
- chr9:14,475–80,871,295, 1,096 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–3,556,314, 58 genes, copy number 5: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1.
- chr11:14,504,874–30,850,559, 230 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:32,435,518–33,774,543, 33 genes, copy number 7 (within-gene range 4–7): WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3.
- chr12:66,767–34,249,958, 850 genes, copy number 5–7 (broad region; genes not listed).
- chr12:64,186,316–69,610,907, 133 genes, copy number 5–6 (broad region; genes not listed).
- chr12:70,180,338–70,637,440, 9 genes, copy number 5 (within-gene range 2–5): LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr14:21,941,128–22,507,723, 78 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–34,965,270, 1,339 genes, copy number 5–6 (broad region; genes not listed).
- chr16:63,703,483–65,576,345, 15 genes, copy number 5: AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922.
- chr16:65,601,101–65,601,698, 1 gene, copy number 5: AC092138.1.
- chr18:20,946,906–27,247,188, 126 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–38,812,945, 384 genes, copy number 6 (broad region; genes not listed).
- chr19:57,065,334–58,605,223, 133 genes, copy number 6–7 (broad region; genes not listed).
- chr22:15,290,718–20,016,823, 206 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
